Somatic mutation profile of tumor specimen ALCH-B786-TTP1-A (aliquot ALCH-B786-TTP1-A-1-0-D-A96E-47) from ALCHEMIST case ALCH-B786, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 72.4 years (26,441 days).
Specimen ALCH-B786-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e05a4311-471c-4380-aa57-c9caa566d5ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B786-NB1-A (Peripheral Whole Blood; tissue type Normal), aliquot ALCH-B786-NB1-A-1-0-D-A96Q-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/51fcd9e3-449e-458d-8c02-15fed175d062

The open-access MAF lists 13 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP45 | c.3011C>T p.A1004V | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as rs1212400408; called by muse, mutect2
- CELF5 | c.1352C>T p.P451L | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs971014909; called by muse, mutect2
- MUC4 | c.12266C>A p.A4089E | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.654); catalogued as rs868408725; called by muse, mutect2
- ABCA2 | c.556G>A p.A186T (on ENST00000614293; = p.A156T on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- CAMSAP3 | c.2219C>T p.P740L | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.085); called by muse, varscan2
- CCDC146 | c.2629G>C p.E877Q | Missense Mutation (SNP) | VAF 8/192 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.334); called by muse, mutect2
- CLCA1 | c.1472G>A p.S491N | Missense Mutation (SNP) | VAF 9/135 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HMCN1 | c.4675G>A p.V1559I | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.111); called by muse, mutect2
- IL13RA2 | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 13/284 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2
- POLA1 | c.2238G>T p.W746C | Missense Mutation (SNP) | VAF 15/309 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); called by muse, mutect2
- FAM171A2 | c.1458C>T p.G486= | Silent (SNP) | VAF 3/20 reads (15%) | called by muse, varscan2
- TAGLN | c.171G>A p.K57= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as COSV54063442; called by muse, mutect2, varscan2
- C11orf96 | chr11:43943799 C>T | 3'Flank (SNP) | VAF 7/53 reads (13%) | catalogued as rs969488784; called by muse, mutect2, varscan2
